Somatic mutation profile of cancer-model specimen HCM-BROD-1078-C49-85B (Adherent Cell Line, passage 10; aliquot HCM-BROD-1078-C49-85B-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-BROD-1078-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 45.9 years (16,769 days).
Specimen HCM-BROD-1078-C49-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a7c2079-a620-480f-8f11-d65ad42e5d40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1078-C49-10A (Blood Derived Normal), aliquot HCM-BROD-1078-C49-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7e98ec7-0a4b-4877-8388-d9cbdf6e80b8

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 11, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 22/463 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs868847374; called by muse, mutect2
- FAM205A | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as rs1456756702; called by mutect2, varscan2
- SERPINA5 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 27/403 reads (7%) | catalogued as rs1008588454, COSV61574946; called by muse, mutect2
- TOMM34 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs756013682; called by muse, mutect2, varscan2
- TTC29 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 101/192 reads (53%) | catalogued as COSV57275304; called by muse, mutect2, varscan2
- ANKRD23 | c.826T>A p.S276T | Missense Mutation (SNP) | VAF 28/673 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- APOB | c.11597C>T p.S3866F | Missense Mutation (SNP) | VAF 34/552 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2
- CACNA2D1 | c.1765A>G p.R589G (on ENST00000356253 / NM_001366867.1; = p.R570G on NM_000722.4) | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- IL3 | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 19/443 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2
- LAMA1 | c.7511T>A p.L2504* | Nonsense Mutation (SNP) | VAF 37/478 reads (8%) | called by muse, mutect2
- SBK3 | c.713C>G p.A238G | Missense Mutation (SNP) | VAF 26/774 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- SETD2 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 9/291 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); called by muse, mutect2
- SLC30A2 | c.904A>G p.T302A | Missense Mutation (SNP) | VAF 186/419 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC45A1 | c.1970A>C p.Q657P | Missense Mutation (SNP) | VAF 148/273 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC4A9 | c.2745G>T p.L915F (on ENST00000507527 / NM_001258428.2; = p.L891F on NM_031467.3) | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TOMM34 | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- TREML1 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 28/761 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ALOX12B | c.1974G>T p.P658= | Silent (SNP) | VAF 359/448 reads (80%) | catalogued as COSV59872390; called by muse, mutect2, varscan2
- ARHGEF18 | c.1822C>T p.L608= (on ENST00000359920 / NM_001130955.2; = p.L504= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/761 reads (6%) | catalogued as COSV100149539; called by muse, mutect2
- CYP27A1 | c.1515G>A p.T505= | Silent (SNP) | VAF 19/485 reads (4%) | catalogued as rs886656814; called by muse, mutect2
- DNAH3 | c.9621C>A p.G3207= | Silent (SNP) | VAF 32/582 reads (5%) | called by muse, mutect2
- LRP5 | c.4344C>T p.F1448= | Silent (SNP) | VAF 180/374 reads (48%) | catalogued as rs1354881700; called by muse, mutect2, varscan2
- MYH15 | c.3078G>A p.E1026= | Silent (SNP) | VAF 201/405 reads (50%) | called by muse, mutect2, varscan2
- PDHA2 | c.510C>T p.P170= | Silent (SNP) | VAF 32/504 reads (6%) | catalogued as rs1239933392; called by muse, mutect2
- RNF187 | c.597C>A p.L199= | Silent (SNP) | VAF 17/537 reads (3%) | called by muse, mutect2
- SLC17A2 | c.897T>C p.Y299= | Silent (SNP) | VAF 147/304 reads (48%) | catalogued as rs139793254; called by muse, mutect2, varscan2
- TSPAN18 | c.375C>T p.Y125= | Silent (SNP) | VAF 149/348 reads (43%) | catalogued as rs758849594; called by muse, mutect2
- ZNF724 | c.981A>G p.K327= | Silent (SNP) | VAF 12/430 reads (3%) | catalogued as rs1171826984; called by muse, mutect2
- DNAJB13 | c.607-68G>T | Intron (SNP) | VAF 20/605 reads (3%) | called by muse, mutect2
